Somatic mutation profile of tumor specimen TCGA-MR-A520-01A (aliquot TCGA-MR-A520-01A-11D-A25V-10) from TCGA case TCGA-MR-A520, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 58.6 years (21,398 days).
Specimen TCGA-MR-A520-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54880734-bb5e-445e-a2a6-3ecb40f69a50.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MR-A520-10A (Blood Derived Normal), aliquot TCGA-MR-A520-10A-01D-A25V-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9b75bcd4-c75c-4d70-b918-08fe27391723

The open-access MAF lists 23 somatic variants for this specimen: 14 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 6, Frame Shift Del 1, RNA 1, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP29 | c.1681G>A p.G561R | Missense Mutation (SNP) | VAF 9/215 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV53112004, COSV99557613; called by muse, mutect2
- GJA8 | c.395G>A p.S132N | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs782766869; called by muse, mutect2, varscan2
- HTR7 | c.430A>G p.I144V | Missense Mutation (SNP) | VAF 71/277 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.031); catalogued as rs777903055; called by muse, mutect2, varscan2
- LZIC | c.148C>G p.L50V | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as rs772109130; called by muse, mutect2, varscan2
- OR5J2 | c.624G>C p.M208I | Missense Mutation (SNP) | VAF 90/292 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV56621172; called by muse, mutect2, varscan2
- SLC17A8 | c.344C>G p.P115R | Missense Mutation (SNP) | VAF 70/251 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0.347); catalogued as COSV60125333; called by muse, mutect2, varscan2
- SLC9A6 | c.1660G>C p.G554R | Missense Mutation (SNP) | VAF 86/137 reads (63%) | SIFT tolerated (0.32); PolyPhen benign (0.315); catalogued as rs782196157; called by muse, mutect2, varscan2
- CCSER1 | c.1025C>T p.A342V | Missense Mutation (SNP) | VAF 65/200 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- COL11A2 | c.771del p.R257Sfs*26 (on ENST00000341947 / NM_080680.3; = p.R257Sfs*18 on NM_080679.2) | Frame Shift Del (DEL) | VAF 66/268 reads (25%) | called by mutect2, varscan2
- FAT3 | c.6886C>G p.L2296V | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.662); called by muse, mutect2
- KIFBP | c.1124C>T p.S375F | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- LRRC69 | c.818T>C p.I273T | Missense Mutation (SNP) | VAF 83/281 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- MYOF | c.4052A>G p.N1351S | Missense Mutation (SNP) | VAF 54/187 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- TMEM61 | c.251G>A p.G84D | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DDOST | c.792C>T p.F264= (on ENST00000415136; = p.F247= on NM_005216.5) | Silent (SNP) | VAF 46/143 reads (32%) | called by muse, mutect2, varscan2
- FIGN | c.552A>G p.E184= | Silent (SNP) | VAF 16/140 reads (11%) | called by mutect2, varscan2
- LRFN1 | c.1137G>A p.A379= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as rs954869382; called by muse, varscan2
- RSC1A1 | c.1722C>G p.A574= | Silent (SNP) | VAF 77/242 reads (32%) | called by muse, mutect2, varscan2
- TOX | c.249G>A p.L83= | Silent (SNP) | VAF 10/208 reads (5%) | called by muse, mutect2
- ZNF423 | c.2067G>A p.L689= (on ENST00000563137 / NM_001379286.1; = p.L681= on NM_015069.4) | Silent (SNP) | VAF 71/228 reads (31%) | called by muse, mutect2, varscan2
- MPRIP | c.2163+3333del | Intron (DEL) | VAF 50/197 reads (25%) | called by mutect2, pindel, varscan2
- SLITRK2 | chrX:145827968 C>A | 3'Flank (SNP) | VAF 64/117 reads (55%) | catalogued as COSV100157843; called by muse, mutect2, varscan2
- ZNF658B | n.2204G>A | RNA (SNP) | VAF 93/338 reads (28%) | called by muse, mutect2, varscan2
